Somatic mutation profile of tumor specimen C3N-01715-02 (aliquot CPT0125090006) from CPTAC case C3N-01715, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.7 years (22,534 days).
Specimen C3N-01715-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d631eaef-ee44-49b9-99c2-bbc6f2f59949.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01715-31 (Blood Derived Normal), aliquot CPT0125120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48749019-a8c0-41fa-82b8-820dec117bec

The open-access MAF lists 889 somatic variants for this specimen: 601 protein-altering or splice-affecting, 177 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 410, Silent 177, Frame Shift Del 89, Intron 54, Frame Shift Ins 39, In Frame Del 23, 3'UTR 22, Nonsense Mutation 17, 5'UTR 14, Splice Region 13, Splice Site 10, 5'Flank 8.

Variants (750 of 889; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 64/562 reads (11%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- KMT2D | c.8488C>T p.R2830* | Nonsense Mutation (SNP) | VAF 77/292 reads (26%) | catalogued as rs727503983, CM105465, COSV56427366; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.350C>G p.T117R | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs63750781, CM950802, CM960965, COSV51617070; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYO15A | c.1185del p.E396Rfs*48 | Frame Shift Del (DEL) | VAF 48/443 reads (11%) | catalogued as rs772536599; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYO7A | c.397del p.H133Tfs*13 | Frame Shift Del (DEL) | VAF 24/234 reads (10%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, pindel
- PNPLA6 | c.2813G>A p.R938H (on ENST00000414982 / NM_001166111.2; = p.R890H on NM_006702.5) | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs121434416, CM081403, COSV55378349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1996A>G p.K666E | Missense Mutation (SNP) | VAF 39/316 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754688962, COSV59206172, COSV59206856; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 16/236 reads (7%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2
- ABCA8 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs139423903; called by muse, varscan2
- ABCB1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 31/331 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1429920034; called by muse, mutect2
- ABO | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 87/670 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.311); catalogued as rs782721438, COSV101505925, COSV71743460; called by muse, mutect2, varscan2
- ACAD8 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 63/545 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371449613, CM063825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACKR3 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs565164449, COSV56021394; called by muse, mutect2, varscan2
- ADAM33 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.018); catalogued as rs1216058743; called by muse, mutect2, varscan2
- ADCK5 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs782320085; called by muse, mutect2, varscan2
- ADGRG4 | c.5812T>A p.S1938T | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs758897711, COSV54951044; called by muse, mutect2, varscan2
- ADHFE1 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.103); catalogued as rs376645357; called by muse, mutect2, varscan2
- ADSS1 | c.741del p.K248Rfs*23 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | catalogued as rs769542442; called by mutect2, pindel, varscan2
- AEBP2 | c.66dup p.G23Rfs*12 | Frame Shift Ins (INS) | VAF 40/376 reads (11%) | catalogued as rs1555180802; called by mutect2, pindel
- AIP | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 71/567 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as rs139947406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG1 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 50/437 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770775485; called by muse, mutect2, varscan2
- ANK2 | c.5426C>T p.A1809V | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs531261130, COSV52148371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD9 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1318434677; called by muse, mutect2
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2
- ANTXR1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 57/480 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58009595; called by muse, mutect2, varscan2
- AOC2 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 29/429 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs267604890, COSV53827971; called by muse, mutect2
- APP | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.603); catalogued as rs532382285, COSV100695946; called by muse, mutect2, varscan2
- ARIH1 | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 50/399 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV65911901; called by muse, mutect2, varscan2
- ARL16 | c.145del p.R49Gfs*56 | Frame Shift Del (DEL) | VAF 15/97 reads (15%) | catalogued as COSV100230698; called by mutect2, pindel, varscan2
- ARMH3 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.145); catalogued as rs752261708; called by muse, mutect2, varscan2
- ASB16 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 13/130 reads (10%) | catalogued as rs372307713; called by muse, mutect2
- ATG2B | c.4868C>T p.P1623L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs370728333; called by muse, mutect2
- ATP13A3 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as COSV99756811; called by muse, mutect2
- BAHCC1 | c.2502dup p.H835Afs*239 | Frame Shift Ins (INS) | VAF 12/88 reads (14%) | catalogued as rs1555653772; called by mutect2, varscan2
- BARHL2 | c.376del p.Q126Sfs*18 | Frame Shift Del (DEL) | VAF 27/233 reads (12%) | catalogued as rs747119215; called by mutect2, pindel, varscan2
- BCOR | c.3781del p.R1261Gfs*33 (on ENST00000378444 / NM_001123385.2; = p.R1227Gfs*33 on NM_017745.6) | Frame Shift Del (DEL) | VAF 26/149 reads (17%) | catalogued as COSV60707801; called by mutect2, pindel, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 28/184 reads (15%) | catalogued as rs768244116; called by mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | catalogued as rs755506199; called by mutect2, varscan2
- BMP2 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs752683518, COSV66577006, COSV66578595; called by muse, mutect2, varscan2
- BMP2K | c.3076C>A p.R1026S | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs780522133, COSV55011105; called by muse, mutect2, varscan2
- BOC | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs746840045; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 18/52 reads (35%) | catalogued as rs749043197; called by mutect2, varscan2
- BTNL8 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754512426, COSV51456653; called by muse, mutect2, varscan2
- C15orf39 | c.1120del p.Q374Rfs*3 | Frame Shift Del (DEL) | VAF 38/331 reads (11%) | catalogued as COSV100641264; called by mutect2, pindel, varscan2
- CACNA1C | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104404676, COSV59706212; called by muse, mutect2, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 17/131 reads (13%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CAMTA1 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs369691511; called by muse, mutect2, varscan2
- CCDC178 | c.2470G>A p.A824T (on ENST00000383096 / NM_001105528.3; = p.A786T on NM_198995.3) | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs200388828, COSV100285008; called by muse, mutect2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 19/162 reads (12%) | catalogued as rs773752200; called by mutect2, pindel
- CCR7 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs141181444, COSV55850487; called by muse, mutect2, varscan2
- CD164L2 | c.383del p.P128Qfs*23 | Frame Shift Del (DEL) | VAF 32/188 reads (17%) | catalogued as rs755393856; called by mutect2, pindel, varscan2
- CD69 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767001061, COSV57302241; called by muse, mutect2, varscan2
- CEP112 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs776010708, COSV67142699; called by muse, mutect2, varscan2
- CEP350 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867400047; called by muse, mutect2
- CEP70 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 32/274 reads (12%) | catalogued as rs751569983; called by muse, mutect2, varscan2
- CFAP46 | c.7654G>A p.G2552S | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs372508852; called by muse, mutect2, varscan2
- CHD5 | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52420803; called by muse, mutect2
- CHD7 | c.2891del p.N964Tfs*13 | Frame Shift Del (DEL) | VAF 21/237 reads (9%) | catalogued as CM126608; called by mutect2, pindel
- CHGB | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs768860358; called by muse, mutect2
- CHST1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV57322551; called by muse, mutect2, varscan2
- CHST13 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs755426222; called by muse, mutect2, varscan2
- CHST14 | c.1034G>C p.R345P | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs991224324; called by muse, mutect2
- CLDN6 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 79/536 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV58509188; called by muse, mutect2, varscan2
- CLRN3 | c.262dup p.T88Nfs*84 | Frame Shift Ins (INS) | VAF 60/510 reads (12%) | catalogued as rs748191748; called by mutect2, pindel
- COL20A1 | c.3619G>A p.V1207M | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.194); catalogued as rs369702957; called by muse, mutect2, varscan2
- COL4A4 | c.999T>A p.D333E | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV61633263; called by muse, mutect2, varscan2
- COL6A6 | c.5150G>A p.R1717H | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as rs756792501; called by muse, mutect2, varscan2
- COL6A6 | c.5722C>T p.R1908C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs376975822; called by muse, mutect2
- CPSF7 | c.-53G>C | Splice Region (SNP) | VAF 26/159 reads (16%) | catalogued as COSV57100470; called by muse, mutect2, varscan2
- CSF1R | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 71/491 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs1256984931, COSV53834937; called by muse, mutect2, varscan2
- CSMD1 | c.9637G>A p.A3213T (on ENST00000520002; = p.A3212T on NM_033225.6) | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as rs551310449, COSV59283291; called by muse, mutect2, varscan2
- CST9 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs569509447, COSV65402446; called by muse, mutect2
- CTC1 | c.2249dup p.G751Rfs*40 | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | catalogued as rs1254586169; called by mutect2, pindel, varscan2
- CTSC | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs373283977; called by muse, mutect2, varscan2
- CYP11B2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 58/551 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs767044154; called by muse, mutect2, varscan2
- DCAF7 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60406735; called by muse, mutect2
- DCHS1 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.19); catalogued as rs1024685143; called by muse, mutect2
- DGKQ | c.2644_2646del p.L882del | In Frame Del (DEL) | VAF 20/138 reads (14%) | catalogued as rs1157315754; called by pindel, varscan2
- DIAPH3 | c.3562G>A p.A1188T | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1350483989; called by muse, mutect2, varscan2
- DLGAP3 | c.254del p.G85Vfs*215 | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | catalogued as rs762874947; called by mutect2, varscan2
- DLGAP5 | c.2385_2386del p.L797Hfs*3 | Frame Shift Del (DEL) | VAF 13/157 reads (8%) | catalogued as rs762360287; called by mutect2, pindel
- DLL4 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 36/309 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1223524485, COSV51070466; called by muse, mutect2, varscan2
- DMD | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1228664222, CM051908, COSV55886844, COSV99922377; called by muse, mutect2, varscan2
- DOCK10 | c.6472C>T p.R2158C | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs774357482; called by muse, mutect2, varscan2
- DOK3 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs775452189; called by muse, mutect2, varscan2
- EEF2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs1238638025; called by muse, mutect2, varscan2
- EIF3B | c.1085del p.G362Efs*28 | Frame Shift Del (DEL) | VAF 34/228 reads (15%) | catalogued as COSV62803535; called by mutect2, pindel, varscan2
- ELAPOR2 | c.1243_1245del p.P415del (on ENST00000450689 / NM_001142749.3; = p.P248del on NM_152748.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 13/107 reads (12%) | catalogued as rs780464668; called by pindel, varscan2
- ELAVL1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 27/178 reads (15%) | catalogued as COSV60969153; called by muse, mutect2, varscan2
- ELOA2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs1304952501; called by muse, mutect2, varscan2
- EP400 | c.8936C>T p.P2979L | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs779505369; called by muse, mutect2, varscan2
- EPB41L3 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1392021881, COSV59453407; called by muse, mutect2, varscan2
- EPHX2 | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1235585858; called by muse, mutect2, varscan2
- EPS15L1 | c.2665C>T p.R889W | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs764162027; called by muse, mutect2, varscan2
- FAM149B1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 44/591 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs968366251, COSV99654940; called by muse, mutect2
- FAM160B1 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs138422469, COSV65087282; called by muse, mutect2, varscan2
- FANCM | c.572C>A p.P191H | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53534174; called by muse, mutect2, varscan2
- FAT3 | c.12677G>T p.G4226V | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53105315; called by muse, mutect2, varscan2
- FECH | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1292029868; called by muse, mutect2, varscan2
- FGF4 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.277); catalogued as rs1194157859; called by muse, mutect2, varscan2
- FLG | c.4193G>A p.S1398N | Missense Mutation (SNP) | VAF 118/823 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1206679606; called by muse, mutect2, varscan2
- FMN2 | c.4065A>T p.Q1355H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60458134; called by muse, mutect2, varscan2
- FOSL2 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs763475600, COSV53105197; called by muse, mutect2, varscan2
- FOXN1 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs2286520; called by muse, mutect2, varscan2
- FOXRED1 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 27/262 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1416090738, COSV55005144; called by muse, mutect2, varscan2
- FRAS1 | c.11920C>T p.R3974W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759074187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FUT6 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 54/352 reads (15%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.564); catalogued as rs766401715; called by muse, mutect2, varscan2
- GAA | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs777372252; called by muse, mutect2, varscan2
- GAB1 | c.50dup p.E18Gfs*34 | Frame Shift Ins (INS) | VAF 23/202 reads (11%) | catalogued as rs755581817; called by mutect2, varscan2
- GABRA4 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 34/309 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as COSV51931816; called by muse, mutect2, varscan2
- GCC1 | c.1835C>T p.A612V | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1349179554; called by muse, mutect2, varscan2
- GET3 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs368392204; called by muse, mutect2, varscan2
- GOLGA3 | c.4360C>T p.H1454Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760366618; called by muse, mutect2, varscan2
- GOLGA8Q | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 61/306 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1284996387; called by muse, mutect2, varscan2
- GRIN2B | c.4229C>T p.T1410M | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as rs779830552; ClinVar: benign; called by muse, mutect2, varscan2
- GRM6 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 110/505 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1370098674; called by muse, mutect2, varscan2
- GTF3C1 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs756447771, COSV62241320; called by muse, mutect2
- HDAC6 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs782123991; called by muse, mutect2
- HNRNPH2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.42); catalogued as rs782446773; called by muse, mutect2, varscan2
- HSF5 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1307796144, COSV60200821; called by muse, mutect2
- IFFO1 | c.1089dup p.R364Afs*19 (on ENST00000396840 / NM_001330324.2; = p.R367Afs*19 on NM_080730.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 24/176 reads (14%) | catalogued as rs750779916; called by mutect2, varscan2
- IGHV4-59 | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1419427382; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 34/276 reads (12%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGB1 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1378099428; called by muse, mutect2, varscan2
- JMJD8 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs200168703, COSV50199059; called by muse, mutect2, varscan2
- KCNA5 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 30/507 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs765380398, COSV52904032, COSV99363787; called by muse, mutect2
- KCNB2 | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.871); catalogued as rs567445185; called by muse, varscan2
- KCNN3 | c.2210C>T p.P737L (on ENST00000618040 / NM_001204087.1; = p.P722L on NM_002249.6) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.228); catalogued as rs774384644, COSV55228679; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 24/192 reads (13%) | catalogued as rs747555402; called by mutect2, pindel, varscan2
- KHDC3L | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 57/417 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs769425065, COSV64863247; called by muse, mutect2, varscan2
- KIAA1522 | c.172dup p.H58Pfs*46 (on ENST00000373480 / NM_001198972.2; = p.H117Pfs*46 on NM_020888.3) | Frame Shift Ins (INS) | VAF 26/184 reads (14%) | catalogued as rs767600627; called by mutect2, varscan2
- KIF15 | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs762847739; called by muse, mutect2, varscan2
- KIF17 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370700388; called by muse, mutect2, varscan2
- KIF22 | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 72/464 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748823568; called by muse, mutect2, varscan2
- KLF15 | c.933G>T p.K311N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750849615; called by muse, mutect2, varscan2
- KLK11 | c.833C>T p.T278M (on ENST00000594768 / NM_144947.3; = p.T246M on NM_006853.3) | Missense Mutation (SNP) | VAF 62/500 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs778575456, COSV59398795; called by muse, mutect2, varscan2
- KMT2D | c.14473C>T p.R4825W | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs117904191; called by muse, mutect2, varscan2
- KPNA4 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62075014; called by muse, mutect2
- LAMC1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs752108997; called by muse, mutect2
- LATS1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53600175; called by muse, mutect2, varscan2
- LCE1D | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 43/159 reads (27%) | PolyPhen benign (0.019); catalogued as rs376151801; called by muse, mutect2, varscan2
- LOXHD1 | c.5467C>T p.R1823W (on ENST00000642948; = p.R1761W on NM_144612.7) | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759919888, COSV56061253; called by muse, mutect2
- LRP6 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 27/284 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs759106535, COSV53786736; called by muse, mutect2
- LRRC4B | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65349270; called by muse, mutect2, varscan2
- LTBP3 | c.3648_3650del p.E1216del (on ENST00000301873 / NM_001130144.3; = p.E1169del on NM_021070.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 79/618 reads (13%) | catalogued as rs1398364354; called by pindel, varscan2
- LYST | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs1361872807; called by muse, mutect2
- MAPK4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs186595195, COSV68541012; called by muse, mutect2
- MAPK8IP3 | c.3906_3908del p.D1302del | In Frame Del (DEL) | VAF 36/293 reads (12%) | catalogued as rs772305360; called by pindel, varscan2
- MAST4 | c.7525G>A p.G2509R (on ENST00000403625 / NM_001164664.2; = p.G2320R on NM_015183.3) | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs760215018; called by muse, mutect2, varscan2
- MCM2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs35343063; called by muse, mutect2, varscan2
- MFN1 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as rs1272208650; called by muse, mutect2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 21/135 reads (16%) | catalogued as rs750307488; called by mutect2, varscan2
- MUC12 | c.2056C>T p.P686S (on ENST00000379442; = p.P543S on NM_001164462.1) | Missense Mutation (SNP) | VAF 54/554 reads (10%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.65); catalogued as rs765249028; called by muse, mutect2
- MUC5B | c.4708G>A p.V1570I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); catalogued as rs200722081; called by muse, mutect2, varscan2
- MUC5B | c.11578G>A p.A3860T | Missense Mutation (SNP) | VAF 75/577 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1247568195; called by muse, mutect2, varscan2
- MYH8 | c.868dup p.Y290Lfs*7 | Frame Shift Ins (INS) | VAF 33/256 reads (13%) | catalogued as rs1319380590; called by mutect2, pindel, varscan2
- MYO9B | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 78/604 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1349805194; called by muse, mutect2, varscan2
- NBPF6 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 44/878 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs937522714, COSV99640497; called by muse, mutect2
- NEB | c.6887C>T p.A2296V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1411704072; called by muse, mutect2, varscan2
- NFKBIZ | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 37/365 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777315234; called by muse, mutect2, varscan2
- NMRK2 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs369195071; called by muse, mutect2, varscan2
- NMT1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs773052955, COSV51959439; called by muse, mutect2
- NOTCH2 | c.6892C>T p.R2298W | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1270274564, COSV56685860; called by muse, mutect2
- NPHS1 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756579664; called by muse, mutect2, varscan2
- NPR1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 59/522 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs779546718, COSV64118127; called by muse, mutect2, varscan2
- NPR1 | c.1818del p.N607Ifs*62 | Frame Shift Del (DEL) | VAF 20/168 reads (12%) | catalogued as rs772189906; called by mutect2, pindel, varscan2
- NR2F6 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.69); catalogued as rs770595526; called by muse, mutect2, varscan2
- NSD2 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767627490; called by muse, mutect2, varscan2
- NT5E | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV57628838; called by muse, mutect2, varscan2
- NUTF2 | c.99+1G>A p.X33_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as COSV54645854; called by muse, mutect2
- OBSCN | c.14027G>A p.R4676Q | Missense Mutation (SNP) | VAF 63/523 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs748800682; called by muse, mutect2, varscan2
- OPA1 | c.2228C>T p.P743L (on ENST00000361510 / NM_130837.3; = p.P688L on NM_015560.3) | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs746579947, COSV62479825; called by muse, mutect2
- OPLAH | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.606); catalogued as rs782146729; called by muse, mutect2, varscan2
- OR52L1 | c.892T>C p.Y298H | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188774432; called by muse, mutect2, varscan2
- OR5D16 | c.676A>G p.T226A | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs981647723; called by muse, mutect2, varscan2
- ORMDL2 | c.392T>C p.L131S | Missense Mutation (SNP) | VAF 74/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201630136; called by muse, mutect2, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 30/220 reads (14%) | catalogued as rs782429503; called by mutect2, pindel
- PAPPA2 | c.2635A>G p.S879G | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs1430605269; called by muse, mutect2
- PAXIP1 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as rs745791091; called by muse, mutect2, varscan2
- PCDHGA1 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 129/432 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs577475018, COSV65299631; called by muse, mutect2, varscan2
- PCDHGA5 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as rs746525916; called by muse, mutect2, varscan2
- PCK1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as rs755135303; called by muse, mutect2, varscan2
- PCLO | c.248+1G>A p.X83_splice | Splice Site (SNP) | VAF 19/172 reads (11%) | catalogued as COSV61625940; called by muse, varscan2
- PDE4D | c.560G>A p.R187Q (on ENST00000340635 / NM_001104631.2; = p.R51Q on NM_006203.4) | Missense Mutation (SNP) | VAF 104/480 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs765474542; called by muse, mutect2, varscan2
- PEX2 | c.535A>G p.K179E | Missense Mutation (SNP) | VAF 21/227 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs1384124243; called by muse, mutect2
- PHIP | c.3768_3770del p.L1257del | In Frame Del (DEL) | VAF 13/81 reads (16%) | catalogued as rs964550052; called by pindel, varscan2
- PIWIL1 | c.1866C>T p.P622= | Splice Region (SNP) | VAF 35/314 reads (11%) | catalogued as rs562377597, COSV55348336; called by muse, mutect2, varscan2
- PKD1 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 48/445 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.88); catalogued as rs749740622; called by muse, mutect2, varscan2
- PKN1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.868); catalogued as rs750915489; called by muse, mutect2, varscan2
- PLAGL2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs763383983; called by muse, mutect2, varscan2
- PLCE1 | c.6902G>A p.R2301Q | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs776445270, COSV99595074; called by muse, mutect2
- PLCZ1 | c.395_397del p.E132del | In Frame Del (DEL) | VAF 12/113 reads (11%) | catalogued as rs1456837081; called by mutect2, pindel
- PLEKHA4 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99612295; called by muse, mutect2, varscan2
- PML | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 63/523 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs77069486; called by muse, mutect2, varscan2
- PPIP5K2 | c.3292G>A p.A1098T | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs984944764; called by muse, mutect2, varscan2
- PPL | c.2967del p.Q990Rfs*31 | Frame Shift Del (DEL) | VAF 55/382 reads (14%) | catalogued as rs762995701; called by mutect2, pindel, varscan2
- PPP1R16B | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201345539, COSV55381861; called by muse, mutect2, varscan2
- PPP1R3C | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53289745; called by muse, mutect2, varscan2
- PRC1 | c.1368dup p.Q457Tfs*16 | Frame Shift Ins (INS) | VAF 27/224 reads (12%) | catalogued as rs1231355293; called by mutect2, pindel, varscan2
- PRDM15 | c.647del p.P216Rfs*22 | Frame Shift Del (DEL) | VAF 36/241 reads (15%) | catalogued as COSV54156899; called by mutect2, pindel, varscan2
- PRKAA1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1433191043, COSV57185721; called by muse, mutect2, varscan2
- PRKCA | c.1406T>C p.V469A | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52579554; called by muse, mutect2, varscan2
- PRR12 | c.2725G>A p.E909K (on ENST00000615927; = p.E1730K on NM_020719.3) | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs774390630, COSV69817178; called by muse, mutect2, varscan2
- PTPRK | c.3112C>T p.R1038C (on ENST00000368215 / NM_001291984.2; = p.R1039C on NM_002844.4) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766336327; called by muse, mutect2, varscan2
- PTPRM | c.2805C>T p.Y935= | Splice Region (SNP) | VAF 17/137 reads (12%) | catalogued as rs1004054600, COSV100154107; called by muse, mutect2, varscan2
- PXN | c.1432G>T p.G478C (on ENST00000228307 / NM_001080855.3; = p.G444C on NM_002859.4) | Missense Mutation (SNP) | VAF 54/537 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57218204; called by muse, mutect2, varscan2
- RALGPS1 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as rs374751575; called by muse, mutect2, varscan2
- RASSF5 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553407065; called by muse, mutect2
- RECQL5 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754357449, COSV58638299; called by muse, mutect2
- RERG | c.395_397del p.E132del | In Frame Del (DEL) | VAF 25/150 reads (17%) | catalogued as rs758989434; called by pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 28/234 reads (12%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- ROMO1 | c.175del p.T59Pfs*2 | Frame Shift Del (DEL) | VAF 49/454 reads (11%) | catalogued as COSV53616533; called by mutect2, pindel, varscan2
- RPL4 | c.282C>T p.N94= | Splice Region (SNP) | VAF 13/72 reads (18%) | catalogued as rs544008700, COSV100328767; called by muse, mutect2, varscan2
- RPN1 | c.1363_1365del p.I455del | In Frame Del (DEL) | VAF 42/320 reads (13%) | catalogued as rs1186229975; called by pindel, varscan2
- RYR1 | c.5461G>A p.D1821N | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.588); catalogued as rs139709595, COSV62089374; called by muse, mutect2, varscan2
- RYR2 | c.13823G>A p.R4608Q | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1553328170, CM148846, COSV63697882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.4944G>T p.K1648N | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV101213397; called by muse, mutect2, varscan2
- RYR3 | c.10046G>A p.R3349Q (on ENST00000389232; = p.R3350Q on NM_001036.6) | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs370501059; called by muse, varscan2
- SAMD11 | c.1237dup p.Q413Pfs*42 | Frame Shift Ins (INS) | VAF 18/120 reads (15%) | catalogued as rs1223597129; called by mutect2, varscan2
- SART1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as rs754233385, COSV56710749; called by muse, mutect2
- SCN1B | c.59dup p.C21Lfs*32 | Frame Shift Ins (INS) | VAF 56/406 reads (14%) | catalogued as rs1568348569; called by mutect2, pindel, varscan2
- SCN9A | c.5542C>T p.R1848C (on ENST00000303354; = p.R1837C on NM_002977.3) | Missense Mutation (SNP) | VAF 29/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1381335907, COSV57622475; called by muse, mutect2
- SCRN2 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV51634736, COSV99274393; called by muse, mutect2, varscan2
- SDK2 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs766963724, COSV101166609; called by muse, mutect2, varscan2
- SECISBP2L | c.2924C>A p.S975Y (on ENST00000559471 / NM_001193489.2; = p.S930Y on NM_014701.4) | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55933903; called by muse, mutect2, varscan2
- SEMA3E | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs779454555, COSV100319243; called by muse, mutect2, varscan2
- SETMAR | c.589A>G p.R197G | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs776571663; called by muse, mutect2
- SIAE | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 55/423 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs766546682; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC37A3 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as rs773189820; called by muse, mutect2, varscan2
- SLC7A4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs759478605, COSV60384776; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLC9A1 | c.895_897del p.F299del | In Frame Del (DEL) | VAF 81/564 reads (14%) | catalogued as rs760438825; called by pindel, varscan2
- SLC9A3 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1305643927, COSV53801601; called by muse, mutect2, varscan2
- SMCO2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as rs535258341; called by muse, mutect2, varscan2
- SNRNP70 | c.46dup p.R16Pfs*2 | Frame Shift Ins (INS) | VAF 24/242 reads (10%) | catalogued as rs1183371144; called by mutect2, pindel
- SOGA1 | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs200024274, COSV52933275; called by muse, mutect2, varscan2
- SORBS3 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs369519218; called by muse, mutect2, varscan2
- SP110 | c.1691del p.P564Lfs*16 | Frame Shift Del (DEL) | VAF 30/254 reads (12%) | catalogued as rs1245290762; called by mutect2, pindel, varscan2
- SPAG7 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 64/536 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs1050465869; called by muse, mutect2, varscan2
- SUPT5H | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs757236653, COSV63240896; called by muse, mutect2
- SUSD2 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as rs748381886; called by muse, mutect2, varscan2
- SYNE3 | c.2376C>T p.R792= | Splice Region (SNP) | VAF 13/103 reads (13%) | catalogued as rs1335352974, COSV62081587; called by muse, mutect2, varscan2
- TAX1BP1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs112084378; called by muse, mutect2
- TDRD12 | c.3415C>T p.Q1139* (on ENST00000444215; = p.Q1144* on NM_001366102.1) | Nonsense Mutation (SNP) | VAF 32/233 reads (14%) | catalogued as rs1568499243; called by muse, mutect2, varscan2
- TECPR1 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1368685802, COSV65783352; called by muse, mutect2, varscan2
- TET3 | c.3973C>T p.H1325Y | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV101328031; called by muse, mutect2, varscan2
- TJP1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 19/114 reads (17%) | catalogued as rs1439465484; called by muse, mutect2, varscan2
- TJP3 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372340881; called by muse, mutect2, varscan2
- TLR9 | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs200911364; called by muse, varscan2
- TMCO4 | c.1114dup p.V372Gfs*221 | Frame Shift Ins (INS) | VAF 23/180 reads (13%) | catalogued as rs1448460164; called by mutect2, varscan2
- TMEM132B | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV54746183; called by muse, varscan2
- TMEM17 | c.84G>T p.E28D | Missense Mutation (SNP) | VAF 45/345 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59023469; called by muse, mutect2, varscan2
- TPCN2 | c.2014A>G p.I672V | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.014); catalogued as rs1355049608; called by muse, mutect2, varscan2
- TPR | c.3287T>C p.L1096P | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66600151; called by muse, mutect2, varscan2
- TRA2B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV52025194; called by muse, mutect2, varscan2
- TRIM44 | c.337A>T p.T113S | Missense Mutation (SNP) | VAF 78/524 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1196630044; called by muse, mutect2, varscan2
- TRIOBP | c.2107C>T p.R703W | Missense Mutation (SNP) | VAF 77/569 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.972); catalogued as rs1440271065; called by muse, mutect2, varscan2
- TTC24 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 59/404 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as rs527644191; called by muse, mutect2, varscan2
- TTN | c.58406C>T p.A19469V (on ENST00000591111; = p.A12045V on NM_003319.4) | Missense Mutation (SNP) | VAF 16/172 reads (9%) | PolyPhen benign (0.035); catalogued as rs370687831; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 46/389 reads (12%) | catalogued as rs754361807; called by mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs761345427; called by mutect2, pindel
- VPS13A | c.6283T>C p.S2095P | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as CD022727; called by muse, mutect2, varscan2
- VPS13C | c.4836_4839del p.C1613Ifs*20 (on ENST00000644861 / NM_020821.3; = p.C1570Ifs*20 on NM_017684.5) | Frame Shift Del (DEL) | VAF 6/73 reads (8%) | catalogued as rs1479319076; called by mutect2, pindel
- VWA3B | c.3763G>A p.G1255R | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs756947295; called by muse, mutect2, varscan2
- VWF | c.4414del p.D1472Tfs*53 | Frame Shift Del (DEL) | VAF 31/333 reads (9%) | catalogued as HM070121, COSV54619244, COSV54621459; called by mutect2, pindel
- WARS2 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV99346747; called by muse, mutect2
- YIPF7 | c.469dup p.C157Lfs*87 | Frame Shift Ins (INS) | VAF 27/205 reads (13%) | catalogued as rs775056622; called by mutect2, pindel, varscan2
- ZACN | c.589_592del p.V198Rfs*5 | Frame Shift Del (DEL) | VAF 30/302 reads (10%) | catalogued as rs766215353; called by mutect2, pindel
- ZFC3H1 | c.5548T>G p.C1850G | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66434267; called by muse, mutect2, varscan2
- ZNF219 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.547); catalogued as rs1161853144, COSV53884912; called by muse, mutect2
- ZNF302 | c.509A>G p.E170G (on ENST00000627982; = p.E91G on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1386409233; called by muse, varscan2
- ZNF34 | c.539del p.G180Efs*57 | Frame Shift Del (DEL) | VAF 25/258 reads (10%) | catalogued as COSV58639295; called by mutect2, pindel
- ZNF423 | c.3328G>A p.G1110R (on ENST00000563137 / NM_001379286.1; = p.G1102R on NM_015069.4) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs552943301; called by muse, mutect2, varscan2
- ZNF488 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs144604527; called by muse, mutect2, varscan2
- ZNF579 | c.1063del p.A355Rfs*50 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as COSV57638435; called by mutect2, pindel, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 28/254 reads (11%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF800 | c.1091G>A p.C364Y | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56178876; called by muse, mutect2
- ZPLD1 | c.5A>G p.E2G (on ENST00000466937 / NM_001329788.1; = p.E18G on NM_175056.2) | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.123); catalogued as COSV60353004; called by muse, mutect2
- ZSCAN22 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.161); catalogued as rs149655686; called by muse, mutect2
- A2ML1 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- A4GALT | c.201del p.T68Pfs*46 | Frame Shift Del (DEL) | VAF 38/314 reads (12%) | called by mutect2, pindel
- ABCA6 | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ABCA6 | c.2110T>C p.W704R | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABCB11 | c.2334G>T p.Q778H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ABCB9 | c.806T>C p.L269P | Missense Mutation (SNP) | VAF 42/337 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACOXL | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY8 | c.2294A>G p.K765R | Missense Mutation (SNP) | VAF 35/530 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- ADD1 | c.1206_1207del p.K403Vfs*2 | Frame Shift Del (DEL) | VAF 26/198 reads (13%) | called by pindel, varscan2
- ADORA2B | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADRA2C | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AFF3 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- AFTPH | c.1241del p.N414Mfs*9 | Frame Shift Del (DEL) | VAF 41/259 reads (16%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.1987_1989del p.L663del (on ENST00000366508; = p.L637del on NM_015446.5) | In Frame Del (DEL) | VAF 34/178 reads (19%) | called by pindel, varscan2
- AHNAK | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AHSA1 | c.237_239del p.F80del | In Frame Del (DEL) | VAF 47/368 reads (13%) | called by pindel, varscan2
- ALK | c.4379del p.E1460Gfs*17 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | called by mutect2, pindel*, varscan2*
- ALPK1 | c.1504A>G p.T502A | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ALPK3 | c.2927G>T p.S976I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- AMIGO2 | c.1393dup p.R465Kfs*30 | Frame Shift Ins (INS) | VAF 44/289 reads (15%) | called by mutect2, pindel, varscan2
- AP2A1 | c.2551del p.Q851Rfs*5 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | called by mutect2, pindel, varscan2
- AP3B1 | c.46dup p.E16Gfs*23 | Frame Shift Ins (INS) | VAF 98/461 reads (21%) | called by mutect2, varscan2
- AP5B1 | c.1014G>C p.L338F | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AREL1 | c.95T>C p.F32S | Missense Mutation (SNP) | VAF 58/594 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.91); called by muse, mutect2
- ARMC5 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.017); called by muse, mutect2
- ASMTL | c.1598A>G p.D533G | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ATG2B | c.1794del p.F598Lfs*32 | Frame Shift Del (DEL) | VAF 15/144 reads (10%) | called by mutect2, pindel, varscan2
- ATP11B | c.1037del p.L346Wfs*14 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- B4GALNT1 | c.677G>T p.S226I | Missense Mutation (SNP) | VAF 103/726 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- BCAN | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2
- BNC2 | c.1817del p.P606Rfs*7 | Frame Shift Del (DEL) | VAF 30/252 reads (12%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRF2 | c.286T>A p.Y96N | Missense Mutation (SNP) | VAF 43/425 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- BRIP1 | c.2446T>C p.W816R | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.8702dup p.P2902Sfs*53 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- C12orf40 | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2
- C5orf63 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- C8B | c.424G>T p.G142W | Missense Mutation (SNP) | VAF 62/554 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNG3 | c.514dup p.S172Kfs*31 | Frame Shift Ins (INS) | VAF 22/172 reads (13%) | called by mutect2, varscan2
- CALR3 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN1 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPRIN2 | c.1987+2T>C p.X663_splice | Splice Site (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2
- CCDC93 | c.1175T>C p.M392T | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD248 | c.2229del p.R744Gfs*61 | Frame Shift Del (DEL) | VAF 26/198 reads (13%) | called by mutect2, pindel
- CD36 | c.1348A>G p.S450G | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDAN1 | c.2476A>T p.K826* | Nonsense Mutation (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
- CDH22 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH26 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH7 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- CEMIP | c.2570C>A p.P857H | Missense Mutation (SNP) | VAF 26/705 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2
- CEP128 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CEP295NL | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CIT | c.2779-5T>C | Splice Region (SNP) | VAF 25/112 reads (22%) | called by muse, mutect2, varscan2
- CLCN6 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLDND1 | c.232T>C p.W78R | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLEC16A | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CLEC18B | c.878-1G>T p.X293_splice | Splice Site (SNP) | VAF 30/662 reads (5%) | called by muse, mutect2
- CMYA5 | c.7268A>G p.D2423G | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- COPS5 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 32/333 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- CRP | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- CSTF2 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 69/503 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CTNNA3 | c.1104del p.K369Rfs*14 | Frame Shift Del (DEL) | VAF 21/145 reads (14%) | called by mutect2, pindel, varscan2
- DBNDD2 | c.235T>C p.C79R | Missense Mutation (SNP) | VAF 73/504 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF10 | c.1337_1339del p.E446del | In Frame Del (DEL) | VAF 8/61 reads (13%) | called by pindel, varscan2
- DCAF12L1 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DCDC1 | c.1358A>G p.N453S | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- DDX24 | c.465_468del p.K156Ifs*54 | Frame Shift Del (DEL) | VAF 30/380 reads (8%) | called by mutect2, pindel
- DERL2 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- DNAAF1 | c.1698+5_1698+6del | Splice Region (DEL) | VAF 52/484 reads (11%) | called by mutect2, pindel
- DNAAF5 | c.1817T>C p.V606A | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2
- DNAH10 | c.12683G>A p.G4228D (on ENST00000409039; = p.G4167D on NM_207437.3) | Missense Mutation (SNP) | VAF 19/419 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); called by muse, mutect2
- DNAH14 | c.9745C>T p.Q3249* (on ENST00000445597; = p.Q4257* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- DNAH3 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DRAM1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.902); called by muse, varscan2
- DSG4 | c.1990G>T p.G664* | Nonsense Mutation (SNP) | VAF 92/718 reads (13%) | called by muse, mutect2, varscan2
- DUOXA1 | c.817A>G p.R273G | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.569); called by muse, mutect2
- DUOXA2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- DYNC1H1 | c.9988del p.E3330Kfs*34 | Frame Shift Del (DEL) | VAF 49/388 reads (13%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.3389T>C p.V1130A | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EIPR1 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- ELMO1 | c.827T>A p.L276* | Nonsense Mutation (SNP) | VAF 26/282 reads (9%) | called by muse, mutect2
- ELP5 | c.479_480del p.K160Sfs*9 | Frame Shift Del (DEL) | VAF 38/288 reads (13%) | called by mutect2, pindel, varscan2
- EML2 | c.1840T>C p.Y614H | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- ENGASE | c.416+1G>A p.X139_splice | Splice Site (SNP) | VAF 45/268 reads (17%) | called by muse, mutect2, varscan2
- ENO4 | c.1167A>T p.E389D (on ENST00000622726; = p.E386D on NM_001242699.2) | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ENTPD1 | c.1074+2T>C p.X358_splice | Splice Site (SNP) | VAF 29/338 reads (9%) | called by muse, mutect2
- EP300 | c.4408del p.M1470Cfs*26 | Frame Shift Del (DEL) | VAF 56/350 reads (16%) | called by pindel, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 50/361 reads (14%) | called by mutect2, pindel, varscan2
- EPHA4 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6L2 | c.3043A>G p.N1015D | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2
- EVC | c.1280dup p.A428Gfs*49 | Frame Shift Ins (INS) | VAF 50/346 reads (14%) | called by mutect2, pindel, varscan2
- F13A1 | c.1514del p.K505Sfs*9 | Frame Shift Del (DEL) | VAF 46/348 reads (13%) | called by mutect2, pindel, varscan2
- FAAP24 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM155B | c.929T>C p.V310A | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- FAM241B | c.145dup p.R49Pfs*18 | Frame Shift Ins (INS) | VAF 41/289 reads (14%) | called by mutect2, pindel, varscan2
- FBLN1 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 62/560 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBXO44 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2
- FGFR1OP2 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHAD1 | c.1982_1984del p.G661del | In Frame Del (DEL) | VAF 31/247 reads (13%) | called by mutect2, pindel, varscan2
- FKRP | c.948dup p.C317Lfs*73 | Frame Shift Ins (INS) | VAF 22/175 reads (13%) | called by mutect2, pindel, varscan2
- FOXD2 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FOXD3 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 55/433 reads (13%) | called by muse, mutect2, varscan2
- FSIP2 | c.630_632del p.M210del | In Frame Del (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- FSIP2 | c.12501del p.K4167Nfs*3 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | called by mutect2, pindel, varscan2
- FUCA2 | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FZD3 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GALC | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GALNT12 | c.1495A>G p.N499D | Missense Mutation (SNP) | VAF 86/624 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAS7 | c.29A>G p.Y10C | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GDF6 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 141/452 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GFER | c.62del p.G21Afs*6 | Frame Shift Del (DEL) | VAF 17/155 reads (11%) | called by mutect2, pindel, varscan2
- GGA3 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); called by muse, mutect2
- GLI3 | c.624del p.H208Qfs*8 | Frame Shift Del (DEL) | VAF 50/568 reads (9%) | called by mutect2, pindel
- GLRA3 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GLYR1 | c.678_679del p.K227Afs*16 | Frame Shift Del (DEL) | VAF 40/260 reads (15%) | called by pindel, varscan2
- GMEB1 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 53/464 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GON4L | c.4553A>G p.Q1518R | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPR158 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GRM8 | c.1721T>C p.I574T | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.339); called by muse, mutect2
- H2BC18 | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 75/687 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- HAO2 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC2 | c.12170_12172del p.E4057del | In Frame Del (DEL) | VAF 42/299 reads (14%) | called by mutect2, pindel, varscan2
- HMOX2 | c.491dup p.Q165Pfs*26 | Frame Shift Ins (INS) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.1352A>G p.E451G | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- HTR3E | c.919dup p.L307Pfs*64 (on ENST00000415389 / NM_001256613.1; = p.L322Pfs*64 on NM_182589.2) | Frame Shift Ins (INS) | VAF 26/235 reads (11%) | called by mutect2, pindel, varscan2
- HYI | c.199+2T>C p.X67_splice | Splice Site (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- HYOU1 | c.2400G>T p.E800D | Missense Mutation (SNP) | VAF 55/380 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ICAM5 | c.1180del p.L394* | Frame Shift Del (DEL) | VAF 29/175 reads (17%) | called by mutect2, pindel, varscan2
- INCENP | c.302T>A p.L101H | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- INTS12 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- IQSEC2 | c.2743C>A p.L915M (on ENST00000642864 / NM_001111125.3; = p.L710M on NM_015075.2) | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRF9 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 49/387 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ITSN2 | c.4690_4691del p.K1564Dfs*13 | Frame Shift Del (DEL) | VAF 24/296 reads (8%) | called by mutect2, pindel
- KCNA3 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KCNC3 | c.1dup p.M1? | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- KDM1A | c.672T>G p.N224K | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KDM2A | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 54/467 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KIAA1671 | c.2846G>A p.R949Q | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIDINS220 | c.4930T>C p.S1644P | Missense Mutation (SNP) | VAF 57/544 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF1C | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KIF26B | c.5503del p.A1835Pfs*41 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | called by mutect2, pindel, varscan2
- KLHL25 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- KMT2A | c.9932C>T p.A3311V | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2
- LAS1L | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LCE2C | c.56A>G p.K19R | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- LEFTY1 | c.127del p.L43Wfs*15 | Frame Shift Del (DEL) | VAF 15/149 reads (10%) | called by mutect2, pindel, varscan2
- LGALS3BP | c.1484_1486del p.S495del | In Frame Del (DEL) | VAF 48/392 reads (12%) | called by mutect2, pindel, varscan2
- LRP12 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LRRC34 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LTB | c.440dup p.G148Wfs*? | Frame Shift Ins (INS) | VAF 17/210 reads (8%) | called by mutect2, pindel
- MACC1 | c.1838dup p.N613Kfs*16 | Frame Shift Ins (INS) | VAF 26/208 reads (13%) | called by mutect2, pindel, varscan2
- MACC1 | c.296A>C p.D99A | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2
- MCIDAS | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCM5 | c.2104-2A>C p.X702_splice | Splice Site (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- MED13 | c.1416del p.L473* | Frame Shift Del (DEL) | VAF 30/276 reads (11%) | called by mutect2, pindel, varscan2
- MED13 | c.693del p.K231Nfs*2 | Frame Shift Del (DEL) | VAF 37/270 reads (14%) | called by mutect2, pindel, varscan2
- MEF2D | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MELTF | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- MINPP1 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MROH8 | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTF1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- MTMR4 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MUC3A | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 14/450 reads (3%) | SIFT tolerated, low confidence (0.16); called by muse, mutect2
- MYCN | c.321del p.N108Tfs*23 | Frame Shift Del (DEL) | VAF 18/210 reads (9%) | called by mutect2, pindel
- MYO16 | c.4357C>A p.H1453N | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5C | c.4568A>G p.Q1523R | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, varscan2
- MYO6 | c.171del p.D58Mfs*8 | Frame Shift Del (DEL) | VAF 35/268 reads (13%) | called by mutect2, pindel, varscan2
- MYRF | c.1667A>G p.H556R (on ENST00000278836 / NM_001127392.3; = p.H547R on NM_013279.4) | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- NAA25 | c.2815_2816del p.K939Dfs*26 | Frame Shift Del (DEL) | VAF 22/226 reads (10%) | called by mutect2, pindel
- NAT10 | c.3036_3037del p.E1012Dfs*24 | Frame Shift Del (DEL) | VAF 26/182 reads (14%) | called by pindel, varscan2
- NBAS | c.4714C>T p.Q1572* | Nonsense Mutation (SNP) | VAF 87/437 reads (20%) | called by muse, mutect2, varscan2
- NBEAL2 | c.2308T>C p.S770P | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- NCOR2 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEPRO | c.993dup p.K332* | Frame Shift Ins (INS) | VAF 15/96 reads (16%) | called by mutect2, pindel
- NET1 | c.822A>T p.K274N (on ENST00000355029 / NM_001047160.3; = p.K220N on NM_005863.5) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- NEURL1 | c.788A>T p.D263V | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- NFIL3 | c.546_547del p.P183Tfs*29 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by pindel, varscan2
- NHSL1 | c.1708dup p.L570Pfs*16 | Frame Shift Ins (INS) | VAF 47/326 reads (14%) | called by mutect2, pindel, varscan2
- NKAPL | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NMRAL1 | c.809del p.R270Lfs*5 | Frame Shift Del (DEL) | VAF 25/263 reads (10%) | called by mutect2, pindel, varscan2
- NODAL | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOS2 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NT5DC2 | c.1237-8G>A | Splice Region (SNP) | VAF 32/215 reads (15%) | called by muse, mutect2, varscan2
- NYAP2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OAS3 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 63/549 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.3268dup p.A1090Gfs*8 | Frame Shift Ins (INS) | VAF 21/221 reads (10%) | called by mutect2, pindel
- OR7G2 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- OTOP3 | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- PARP1 | c.2525A>G p.E842G | Missense Mutation (SNP) | VAF 56/575 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2
- PBRM1 | c.4045del p.L1349Wfs*35 | Frame Shift Del (DEL) | VAF 35/184 reads (19%) | called by mutect2, pindel, varscan2
- PCDHB4 | c.431A>T p.N144I | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCDHB6 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA11 | c.442A>G p.I148V | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDPN | c.388A>G p.T130A (on ENST00000621990; = p.T206A on NM_006474.4) | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- PECR | c.104T>G p.V35G | Missense Mutation (SNP) | VAF 56/474 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PHACTR3 | c.743dup p.N248Kfs*48 | Frame Shift Ins (INS) | VAF 16/163 reads (10%) | called by mutect2, pindel
- PI15 | c.467A>T p.D156V | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PIANP | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 38/395 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); called by muse, mutect2
- PIAS4 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 43/316 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PIGR | c.2199G>A p.R733= | Splice Region (SNP) | VAF 35/349 reads (10%) | called by muse, mutect2, varscan2
- PKD2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- PLA1A | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PLA2G4E | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.435); called by muse, mutect2
- PLCG1 | c.1800G>A p.W600* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | called by muse, mutect2, varscan2
- PLXDC2 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA2 | c.4442C>T p.A1481V | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PNPLA7 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, mutect2
- PPP2R3A | c.1922G>A p.R641K | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRCC | c.316del p.E106Rfs*40 | Frame Shift Del (DEL) | VAF 26/161 reads (16%) | called by mutect2, pindel, varscan2
- PRND | c.-11-2A>G | Splice Site (SNP) | VAF 26/410 reads (6%) | called by muse, mutect2
- PRRX2 | c.350A>G p.Q117R | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PRSS37 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PRSS38 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 35/396 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- PUDP | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PXMP2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2
- PYROXD1 | c.1411T>C p.F471L | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- QRICH2 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 68/433 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RAI1 | c.4199G>A p.C1400Y | Missense Mutation (SNP) | VAF 54/899 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- RAPGEF2 | c.1564del p.S522Vfs*12 | Frame Shift Del (DEL) | VAF 38/346 reads (11%) | called by mutect2, pindel
- RIN2 | c.1462_1464del p.S488del (on ENST00000255006 / NM_001242581.1; = p.S439del on NM_018993.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 56/451 reads (12%) | called by pindel, varscan2
- RIPPLY2 | c.335A>T p.Y112F | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- RMDN3 | c.604T>C p.C202R | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RNF220 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- ROBO3 | c.1614G>A p.M538I | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- RPAIN | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPL5 | c.3+8G>A | Splice Region (SNP) | VAF 48/544 reads (9%) | called by muse, mutect2
- RPS5 | c.560_562del p.S187del | In Frame Del (DEL) | VAF 22/260 reads (8%) | called by mutect2, pindel
- RPTOR | c.3932C>T p.P1311L | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RTF1 | c.753dup p.L252Tfs*22 | Frame Shift Ins (INS) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- RTL1 | c.2876A>G p.N959S | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RUNX1T1 | c.1262del p.P421Qfs*6 (on ENST00000265814 / NM_001198628.1; = p.P394Qfs*6 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/447 reads (7%) | called by mutect2, pindel
- RUVBL1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- S100PBP | c.471T>A p.D157E | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SAMD10 | c.271del p.Q91Rfs*21 | Frame Shift Del (DEL) | VAF 23/174 reads (13%) | called by mutect2, pindel, varscan2
- SCAF8 | c.1333T>C p.S445P | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCML4 | c.1120_1122del p.E374del | In Frame Del (DEL) | VAF 25/224 reads (11%) | called by mutect2, pindel
- SCNN1B | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SESN2 | c.1004del p.P335Lfs*17 | Frame Shift Del (DEL) | VAF 20/177 reads (11%) | called by mutect2, pindel, varscan2
- SETX | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- SF3B4 | c.1060del p.R354Efs*26 | Frame Shift Del (DEL) | VAF 14/119 reads (12%) | called by mutect2, pindel, varscan2
- SHANK3 | c.2451del p.A819Rfs*67 | Frame Shift Del (DEL) | VAF 18/131 reads (14%) | called by mutect2, pindel
- SIGLEC11 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SINHCAF | c.478dup p.S160Ffs*20 | Frame Shift Ins (INS) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- SLC17A4 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SLC34A1 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 55/492 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- SLC38A1 | c.1406G>A p.S469N | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SLC3A2 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 34/321 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- SMARCA2 | c.1477_1479del p.K493del | In Frame Del (DEL) | VAF 29/283 reads (10%) | called by pindel, varscan2
- SMARCC1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 25/144 reads (17%) | called by muse, mutect2, varscan2
- SMCO2 | c.862T>C p.F288L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.248); called by muse, mutect2
- SOGA3 | c.890dup p.A298Cfs*75 | Frame Shift Ins (INS) | VAF 18/133 reads (14%) | called by mutect2, pindel, varscan2
- SP8 | c.592G>A p.A198T (on ENST00000361443 / NM_198956.4; = p.A216T on NM_182700.6) | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.143); called by muse, mutect2
- SPIRE1 | c.1770dup p.G591Rfs*25 (on ENST00000409402 / NM_001128626.2; = p.G577Rfs*25 on NM_020148.3) | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- SPNS2 | c.795G>A p.V265= | Splice Region (SNP) | VAF 51/463 reads (11%) | called by muse, mutect2, varscan2
- SPOCK1 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- SRA1 | c.246_249del p.S82Rfs*28 | Frame Shift Del (DEL) | VAF 25/154 reads (16%) | called by mutect2, pindel, varscan2
- SRC | c.770del p.G257Afs*44 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.2548del p.V850* | Frame Shift Del (DEL) | VAF 123/739 reads (17%) | called by mutect2, pindel, varscan2
- SRL | c.1188del p.N397Tfs*97 | Frame Shift Del (DEL) | VAF 67/423 reads (16%) | called by mutect2, pindel, varscan2
- SRSF2 | c.581del p.P194Qfs*38 (on ENST00000359995 / NM_001195427.2; = p.P194Qfs*50 on NM_003016.4) | Frame Shift Del (DEL) | VAF 32/181 reads (18%) | called by mutect2, pindel, varscan2
- STK35 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SUMF2 | c.640C>A p.L214M (on ENST00000652303; = p.L195M on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TBC1D16 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIAM2 | c.863dup p.P289Afs*32 | Frame Shift Ins (INS) | VAF 46/297 reads (15%) | called by mutect2, pindel, varscan2
- TLR4 | c.827C>T p.A276V (on ENST00000355622 / NM_138554.5; = p.A236V on NM_003266.4) | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- TLR9 | c.2450A>T p.D817V | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLR9 | c.1862T>C p.L621P | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TMEM106B | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TMEM127 | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM163 | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- TMEM183A | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TMEM63A | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TMPRSS5 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2
- TNFRSF10D | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TNIP1 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2
- TPCN2 | c.294del p.F98Lfs*27 | Frame Shift Del (DEL) | VAF 18/228 reads (8%) | called by mutect2, pindel
- TRIL | c.505del p.A169Rfs*34 | Frame Shift Del (DEL) | VAF 30/223 reads (13%) | called by mutect2, pindel, varscan2
- TRIM49C | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 18/345 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- TRMT2A | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- TTBK1 | c.3077dup p.V1027Gfs*9 | Frame Shift Ins (INS) | VAF 12/132 reads (9%) | called by mutect2, pindel
- TTC39B | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.68114A>G p.K22705R (on ENST00000591111; = p.K15281R on NM_003319.4) | Missense Mutation (SNP) | VAF 23/156 reads (15%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUT4 | c.1429T>C p.C477R | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- TXNDC16 | c.1030A>C p.I344L | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- UBAP2L | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 49/368 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UBE3A | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- UBFD1 | c.483A>T p.L161F | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2
- UGT1A8 | c.351del p.F117Lfs*17 | Frame Shift Del (DEL) | VAF 19/157 reads (12%) | called by mutect2, pindel, varscan2
- VGLL1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- VIPR2 | c.909A>G p.I303M | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- VPS13A | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13B | c.3309G>A p.W1103* | Nonsense Mutation (SNP) | VAF 55/509 reads (11%) | called by muse, mutect2, varscan2
- VPS45 | c.1454A>C p.N485T | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2
- VSIG10 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2
- WASHC4 | c.2275A>G p.T759A | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR17 | c.2922+2T>C p.X974_splice | Splice Site (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- XPO5 | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- YARS1 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ZBTB32 | c.1268_1269del p.H423Rfs*70 | Frame Shift Del (DEL) | VAF 20/174 reads (11%) | called by pindel, varscan2
- ZBTB41 | c.1870del p.I624Yfs*88 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- ZBTB45 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 24/247 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZC3H4 | c.2890_2892del p.K964del | In Frame Del (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2
- ZFHX3 | c.6064T>C p.Y2022H | Missense Mutation (SNP) | VAF 81/550 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ZFHX4 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 45/467 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2
- ZFHX4 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); called by muse, mutect2
- ZGRF1 | c.4640dup p.N1547Kfs*7 | Frame Shift Ins (INS) | VAF 22/226 reads (10%) | called by mutect2, pindel
- ZKSCAN8 | c.541dup p.Q181Pfs*43 | Frame Shift Ins (INS) | VAF 29/180 reads (16%) | called by mutect2, pindel, varscan2
- ZMPSTE24 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF146 | c.304T>C p.C102R | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF345 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ZNF366 | c.1430A>G p.Y477C | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF439 | c.1144T>C p.Y382H | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ZNF469 | c.5795G>T p.G1932V (on ENST00000437464; = p.G1960V on NM_001367624.2) | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF48 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF579 | c.107del p.G36Afs*29 | Frame Shift Del (DEL) | VAF 14/101 reads (14%) | called by mutect2, pindel, varscan2
- ZNF628 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.196); called by muse, mutect2
- ZNF776 | c.366del p.K122Nfs*31 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | called by mutect2, varscan2
- ZNF83 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.656); called by muse, varscan2
- ZNRF1 | c.222dup p.A75Rfs*38 | Frame Shift Ins (INS) | VAF 15/148 reads (10%) | called by mutect2, pindel
- AASDH | c.1947C>T p.S649= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as rs763808403, COSV52708510; called by muse, mutect2, varscan2
- ABCA1 | c.1089G>A p.E363= | Silent (SNP) | VAF 25/394 reads (6%) | catalogued as rs1461964626; called by muse, mutect2
- ABCA7 | c.4465C>A p.R1489= | Silent (SNP) | VAF 36/212 reads (17%) | catalogued as CM1512526; called by muse, mutect2, varscan2
- ABCC8 | c.339G>A p.A113= | Silent (SNP) | VAF 70/574 reads (12%) | catalogued as rs1161988958; called by muse, mutect2, varscan2
- ADPRHL1 | c.549C>A p.A183= | Silent (SNP) | VAF 26/254 reads (10%) | catalogued as COSV62910012; called by muse, mutect2, varscan2
- AGPAT1 | c.217C>T p.L73= | Silent (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- AIFM3 | c.396C>T p.G132= | Silent (SNP) | VAF 33/258 reads (13%) | catalogued as rs749009581; called by muse, mutect2, varscan2
- AKAP6 | c.1911T>C p.L637= | Silent (SNP) | VAF 34/278 reads (12%) | called by muse, mutect2, varscan2
- AMFR | c.1740C>T p.R580= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- ANKRD52 | c.150C>T p.Y50= | Silent (SNP) | VAF 32/273 reads (12%) | catalogued as rs745548050; called by muse, mutect2, varscan2
- APCDD1L | c.1104G>A p.T368= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs771870241; called by muse, mutect2, varscan2
- APCDD1L | c.600C>T p.R200= | Silent (SNP) | VAF 12/318 reads (4%) | catalogued as rs1158284668, COSV64487132; called by muse, mutect2
- ASXL3 | c.6060A>G p.P2020= | Silent (SNP) | VAF 27/232 reads (12%) | catalogued as rs369151165; called by muse, varscan2
- ATG2A | c.1812C>A p.A604= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV65968798; called by muse, mutect2, varscan2
- AUTS2 | c.765G>A p.T255= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs758258700, COSV61381280; called by muse, mutect2, varscan2
- BLK | c.900C>T p.Y300= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as rs139994406; called by muse, mutect2, varscan2
- BMERB1 | c.585T>C p.C195= | Silent (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2
- CAMSAP3 | c.2457C>T p.P819= | Silent (SNP) | VAF 39/276 reads (14%) | catalogued as rs747913590; called by muse, mutect2, varscan2
- CASK | c.573C>T p.V191= | Silent (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
- CASKIN1 | c.4269C>T p.A1423= | Silent (SNP) | VAF 29/207 reads (14%) | catalogued as rs764298665; called by muse, mutect2, varscan2
- CAVIN1 | c.651C>T p.R217= | Silent (SNP) | VAF 22/284 reads (8%) | catalogued as rs1181667379; called by muse, mutect2
- CCDC9B | c.285G>A p.E95= | Silent (SNP) | VAF 30/268 reads (11%) | catalogued as rs1225234929; called by muse, mutect2, varscan2
- CDC42BPB | c.4536C>T p.L1512= | Silent (SNP) | VAF 38/346 reads (11%) | catalogued as rs1017268510; called by muse, mutect2, varscan2
- CDH15 | c.558C>T p.N186= | Silent (SNP) | VAF 35/249 reads (14%) | catalogued as rs553396027, COSV57026845; called by muse, mutect2, varscan2
- CEP295 | c.4857A>G p.K1619= | Silent (SNP) | VAF 21/234 reads (9%) | catalogued as rs920361291; called by muse, mutect2
- CGB5 | c.480C>T p.T160= | Silent (SNP) | VAF 17/206 reads (8%) | called by muse, mutect2, varscan2
- CHD5 | c.1299C>A p.A433= | Silent (SNP) | VAF 6/39 reads (15%) | called by mutect2, varscan2
- COL8A1 | c.174A>G p.V58= | Silent (SNP) | VAF 58/487 reads (12%) | catalogued as COSV104369388; called by muse, mutect2, varscan2
- COPS2 | c.1215C>T p.V405= | Silent (SNP) | VAF 31/206 reads (15%) | called by muse, mutect2, varscan2
- CPXM1 | c.531C>T p.D177= | Silent (SNP) | VAF 23/196 reads (12%) | catalogued as rs149725071; called by muse, mutect2, varscan2
- CRKL | c.720G>A p.A240= | Silent (SNP) | VAF 40/262 reads (15%) | catalogued as rs755185083; called by muse, mutect2, varscan2
- CRTAC1 | c.795C>T p.N265= | Silent (SNP) | VAF 34/250 reads (14%) | called by muse, mutect2, varscan2
- CYP7B1 | c.93G>T p.L31= | Silent (SNP) | VAF 49/414 reads (12%) | catalogued as rs1294845737; called by muse, mutect2, varscan2
- DEFB129 | c.348T>C p.F116= | Silent (SNP) | VAF 70/517 reads (14%) | called by muse, mutect2, varscan2
- DNAH10 | c.4524C>A p.I1508= (on ENST00000409039; = p.I1447= on NM_207437.3) | Silent (SNP) | VAF 46/440 reads (10%) | catalogued as COSV68993698; called by muse, mutect2
- DNAJB7 | c.159C>T p.Y53= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs372594873; called by muse, mutect2, varscan2
- DOCK3 | c.4119C>T p.Y1373= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs531449349, COSV56504016, COSV56506594; called by muse, mutect2
- DOK7 | c.966G>A p.L322= | Silent (SNP) | VAF 23/188 reads (12%) | called by muse, mutect2, varscan2
- DPM1 | c.547T>C p.L183= | Silent (SNP) | VAF 26/233 reads (11%) | called by muse, mutect2, varscan2
- DRGX | c.72T>C p.F24= | Silent (SNP) | VAF 40/336 reads (12%) | called by muse, mutect2, varscan2
- DST | c.6729A>G p.T2243= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as rs370484930; called by muse, mutect2, varscan2
- EFR3A | c.345T>C p.L115= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- EIF2B4 | c.816C>T p.S272= (on ENST00000347454 / NM_001034116.2; = p.S271= on NM_015636.3) | Silent (SNP) | VAF 133/665 reads (20%) | called by muse, mutect2, varscan2
- EIF3B | c.1791C>T p.N597= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as rs754459941, COSV62804433; called by muse, mutect2, varscan2
- EN2 | c.510C>T p.G170= | Silent (SNP) | VAF 24/248 reads (10%) | catalogued as rs754732993; called by muse, mutect2
- EPHA5 | c.858C>T p.I286= | Silent (SNP) | VAF 25/202 reads (12%) | catalogued as rs767238890, COSV56628241; called by muse, mutect2, varscan2
- EPHA6 | c.2676C>T p.D892= (on ENST00000389672 / NM_001080448.3; = p.D284= on NM_173655.4) | Silent (SNP) | VAF 39/336 reads (12%) | called by muse, mutect2, varscan2
- ERCC2 | c.513C>T p.P171= | Silent (SNP) | VAF 67/407 reads (16%) | catalogued as rs764710141, COSV99676236; called by muse, mutect2, varscan2
- ERCC6 | c.1197T>A p.G399= | Silent (SNP) | VAF 45/259 reads (17%) | called by muse, mutect2, varscan2
- ERVV-2 | c.702G>A p.S234= | Silent (SNP) | VAF 25/250 reads (10%) | catalogued as rs1319087087, COSV74153548; called by mutect2, varscan2
- FAM135B | c.3729C>T p.F1243= | Silent (SNP) | VAF 35/521 reads (7%) | catalogued as rs1310598121, COSV52708517; called by muse, mutect2
- FAM13B | c.2229G>A p.R743= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV50369080; called by muse, mutect2, varscan2
- FAM78B | c.124C>T p.L42= | Silent (SNP) | VAF 25/194 reads (13%) | called by muse, mutect2, varscan2
- FASN | c.1182C>G p.G394= | Silent (SNP) | VAF 73/610 reads (12%) | called by muse, mutect2, varscan2
- FCGBP | c.9195C>T p.C3065= | Silent (SNP) | VAF 54/631 reads (9%) | catalogued as rs1321951948; called by muse, varscan2
- FGA | c.837C>T p.T279= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as rs763049586; called by muse, mutect2, varscan2
- FKBP6 | c.66C>T p.Y22= | Silent (SNP) | VAF 45/507 reads (9%) | catalogued as rs1322846011, COSV52720500; called by muse, mutect2, varscan2
- FLG2 | c.3273A>G p.Q1091= | Silent (SNP) | VAF 51/535 reads (10%) | called by muse, mutect2
- FOXG1 | c.729G>A p.P243= | Silent (SNP) | VAF 57/368 reads (15%) | catalogued as rs774525510, COSV57395668; ClinVar: likely benign; called by muse, mutect2, varscan2
- FPR2 | c.501A>G p.V167= | Silent (SNP) | VAF 42/400 reads (11%) | called by muse, mutect2, varscan2
- FRMPD2 | c.270A>G p.L90= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- FSBP | c.615G>A p.S205= | Silent (SNP) | VAF 19/187 reads (10%) | catalogued as rs570469619, COSV52594708; called by muse, mutect2, varscan2
- FTSJ3 | c.867C>T p.D289= | Silent (SNP) | VAF 64/498 reads (13%) | called by muse, varscan2
- GNAT2 | c.972C>A p.T324= | Silent (SNP) | VAF 39/272 reads (14%) | called by muse, mutect2, varscan2
- GPR26 | c.369G>A p.A123= | Silent (SNP) | VAF 10/277 reads (4%) | catalogued as COSV52933137; called by muse, mutect2
- GPR87 | c.555A>G p.T185= | Silent (SNP) | VAF 38/408 reads (9%) | called by muse, mutect2
- H2AC16 | c.348A>G p.L116= | Silent (SNP) | VAF 8/221 reads (4%) | called by muse, mutect2
- H3C10 | c.9T>C p.R3= | Silent (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- HGD | c.861A>G p.S287= | Silent (SNP) | VAF 66/501 reads (13%) | catalogued as COSV52196233; called by muse, mutect2, varscan2
- HID1 | c.1266T>C p.G422= | Silent (SNP) | VAF 36/348 reads (10%) | called by muse, mutect2, varscan2
- HSPA12A | c.45G>A p.T15= | Silent (SNP) | VAF 32/316 reads (10%) | catalogued as rs1554882604, COSV65020951, COSV65021134; called by muse, varscan2
- IFFO1 | c.504G>A p.A168= | Silent (SNP) | VAF 37/260 reads (14%) | catalogued as rs1437117217; called by muse, mutect2, varscan2
- IGHA2 | c.219G>A p.P73= | Silent (SNP) | VAF 44/377 reads (12%) | catalogued as rs781958889; called by muse, mutect2, varscan2
- IL18RAP | c.780A>G p.T260= | Silent (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.1464G>T p.G488= | Silent (SNP) | VAF 27/189 reads (14%) | catalogued as rs749307369; called by muse, mutect2, varscan2
- IZUMO2 | c.198G>T p.R66= | Silent (SNP) | VAF 15/124 reads (12%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1371C>T p.G457= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as rs1393661676; called by muse, mutect2, varscan2
- KCNA3 | c.240C>T p.G80= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as rs1369854327; called by muse, mutect2
- KCNJ4 | c.556C>T p.L186= | Silent (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- KCTD11 | c.180C>T p.G60= (on ENST00000333751 / NM_001363642.1; = p.G21= on NM_001002914.2) | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs771444276; called by muse, mutect2, varscan2
- KHDRBS2 | c.72G>A p.A24= | Silent (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- KIF17 | c.1338C>T p.D446= | Silent (SNP) | VAF 52/315 reads (17%) | catalogued as rs765789636; called by muse, mutect2, varscan2
- KIF5C | c.243G>A p.T81= | Silent (SNP) | VAF 34/269 reads (13%) | catalogued as rs186518670; called by muse, mutect2, varscan2
- KLHDC7B | c.456G>T p.G152= (on ENST00000395676; = p.G793= on NM_138433.5) | Silent (SNP) | VAF 16/91 reads (18%) | called by muse, mutect2, varscan2
- KLK4 | c.495G>A p.L165= | Silent (SNP) | VAF 62/578 reads (11%) | called by muse, mutect2, varscan2
- KRT20 | c.186C>T p.G62= | Silent (SNP) | VAF 35/283 reads (12%) | catalogued as rs1488312655; called by muse, mutect2, varscan2
- KRT6A | c.9C>T p.S3= | Silent (SNP) | VAF 144/700 reads (21%) | called by muse, mutect2, varscan2
- KRTAP5-2 | c.81C>T p.G27= | Silent (SNP) | VAF 20/144 reads (14%) | called by mutect2, varscan2
- LDHA | c.990G>A p.L330= | Silent (SNP) | VAF 32/278 reads (12%) | catalogued as rs558872434; called by muse, mutect2, varscan2
- LEUTX | c.31C>T p.L11= | Silent (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- LHX3 | c.945C>T p.Y315= (on ENST00000371748 / NM_178138.6; = p.Y320= on NM_014564.5) | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1357275975; called by muse, mutect2, varscan2
- LRP1 | c.1065G>A p.G355= | Silent (SNP) | VAF 77/343 reads (22%) | catalogued as rs747547972; called by muse, mutect2, varscan2
- LRRTM2 | c.522A>G p.V174= | Silent (SNP) | VAF 56/239 reads (23%) | called by muse, mutect2, varscan2
- LTBP4 | c.4683C>T p.D1561= (on ENST00000308370 / NM_001042544.1; = p.D1524= on NM_003573.2) | Silent (SNP) | VAF 32/216 reads (15%) | catalogued as rs1365889140; ClinVar: likely benign; called by muse, mutect2, varscan2
- LYST | c.39G>C p.L13= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- MAD1L1 | c.2055C>A p.T685= | Silent (SNP) | VAF 22/183 reads (12%) | catalogued as rs377713158; called by muse, mutect2, varscan2
- MKI67 | c.7896A>G p.T2632= | Silent (SNP) | VAF 51/447 reads (11%) | called by mutect2, varscan2
- MOB2 | c.237G>A p.T79= | Silent (SNP) | VAF 27/272 reads (10%) | catalogued as rs1351803509, COSV57318292; called by muse, mutect2, varscan2
- MTM1 | c.1131C>T p.D377= | Silent (SNP) | VAF 63/469 reads (13%) | catalogued as rs1557414507, COSV100080658; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYBPC3 | c.1815C>T p.D605= | Silent (SNP) | VAF 17/202 reads (8%) | catalogued as rs768380030, COSV57029575; ClinVar: likely benign; called by muse, mutect2
- MYO18B | c.4344T>C p.D1448= | Silent (SNP) | VAF 15/263 reads (6%) | catalogued as rs1296503471; called by muse, mutect2
- NAA80 | c.576G>A p.E192= (on ENST00000417393 / NM_001200018.2; = p.E214= on NM_012191.4) | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1391162709; called by muse, mutect2
- NDST1 | c.1989C>A p.P663= | Silent (SNP) | VAF 45/397 reads (11%) | called by muse, mutect2, varscan2
- NEUROG3 | c.6G>A p.T2= | Silent (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4473G>A p.T1491= | Silent (SNP) | VAF 50/479 reads (10%) | catalogued as rs941691193, COSV53056929; called by muse, mutect2, varscan2
- NT5C1B | c.708G>A p.S236= (on ENST00000359846 / NM_001199086.2; = p.S176= on NM_033253.4) | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV100410238; called by muse, mutect2, varscan2
- NTN4 | c.981C>T p.N327= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs374055562, COSV59219495; called by muse, mutect2
- OBSCN | c.13833C>A p.P4611= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV52758050; called by muse, mutect2
- OLFM2 | c.198G>A p.R66= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as rs751745664; called by muse, mutect2, varscan2
- OR1K1 | c.426C>T p.C142= | Silent (SNP) | VAF 33/216 reads (15%) | catalogued as rs780396929, COSV52956460; called by muse, mutect2, varscan2
- OR4D10 | c.171G>A p.T57= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as rs765052417, COSV101597011; called by muse, mutect2, varscan2
- OR8S1 | c.1062G>A p.A354= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs1480531577, COSV59600243; called by muse, mutect2
- OSCP1 | c.603G>A p.P201= (on ENST00000356637 / NM_001330493.1; = p.P191= on NM_145047.5) | Silent (SNP) | VAF 45/319 reads (14%) | catalogued as rs146439686, COSV99347582; called by muse, mutect2, varscan2
- OTUD7A | c.2355C>T p.G785= (on ENST00000307050 / NM_001382637.1; = p.G778= on NM_130901.3) | Silent (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- PAEP | c.489G>A p.R163= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs749179379; called by muse, mutect2, varscan2
- PAPPA | c.1200G>A p.V400= | Silent (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- PAQR6 | c.558A>G p.T186= (on ENST00000292291 / NM_001272108.2; = p.T80= on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/362 reads (16%) | called by muse, mutect2, varscan2
- PER1 | c.3111C>T p.S1037= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as rs375292406; called by muse, mutect2, varscan2
- PHKA1 | c.3465G>A p.V1155= | Silent (SNP) | VAF 27/244 reads (11%) | catalogued as rs1262683844; called by muse, mutect2, varscan2
- PIK3CG | c.855G>A p.T285= | Silent (SNP) | VAF 42/408 reads (10%) | catalogued as rs144765743; called by muse, mutect2
- PITPNM2 | c.1368C>T p.F456= | Silent (SNP) | VAF 108/478 reads (23%) | catalogued as rs971868992, COSV54898816; called by muse, mutect2, varscan2
- POLH | c.1947A>G p.E649= | Silent (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- PPP1R3F | c.21G>A p.V7= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1459652793; called by muse, mutect2, varscan2
- PRSS23 | c.927C>T p.C309= | Silent (SNP) | VAF 58/318 reads (18%) | catalogued as rs922808925; called by muse, mutect2, varscan2
- PRUNE2 | c.7557T>C p.I2519= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, varscan2
- PSMG3 | c.333G>T p.A111= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as rs773166864; called by muse, mutect2, varscan2
- PTCHD4 | c.2008C>T p.L670= | Silent (SNP) | VAF 34/249 reads (14%) | called by muse, mutect2, varscan2
- PTGER1 | c.447C>A p.V149= | Silent (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- PTOV1 | c.369C>A p.A123= | Silent (SNP) | VAF 33/330 reads (10%) | called by muse, mutect2, varscan2
- PTPRF | c.1380C>T p.N460= | Silent (SNP) | VAF 45/321 reads (14%) | catalogued as rs766810518; called by muse, mutect2, varscan2
- PTPRS | c.1899G>T p.T633= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV53628738; called by muse, mutect2
- RBM12 | c.2493C>T p.P831= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs560955830; called by muse, mutect2, varscan2
- RET | c.886C>T p.L296= | Silent (SNP) | VAF 69/580 reads (12%) | called by muse, mutect2, varscan2
- RGS22 | c.363T>A p.I121= | Silent (SNP) | VAF 36/134 reads (27%) | called by muse, mutect2, varscan2
- RIMBP3 | c.3600T>G p.T1200= | Silent (SNP) | VAF 40/536 reads (7%) | called by muse, mutect2
- RPTN | c.774C>T p.H258= | Silent (SNP) | VAF 38/333 reads (11%) | catalogued as rs760194975; called by muse, mutect2, varscan2
- RXRA | c.51C>A p.S17= | Silent (SNP) | VAF 62/571 reads (11%) | called by muse, mutect2, varscan2
- SART1 | c.1605C>A p.R535= | Silent (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- SCAF8 | c.1221T>A p.R407= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- SCRT2 | c.207C>T p.A69= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs752127643; called by mutect2, varscan2
- SCUBE1 | c.1203C>T p.C401= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as rs746666478; called by muse, mutect2, varscan2
- SDE2 | c.423G>A p.Q141= | Silent (SNP) | VAF 29/315 reads (9%) | called by muse, mutect2
- SDK2 | c.4887C>T p.N1629= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs770759494; called by muse, mutect2, varscan2
- SELP | c.1989T>G p.G663= | Silent (SNP) | VAF 59/552 reads (11%) | called by muse, mutect2, varscan2
- SH2B3 | c.657C>T p.R219= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as rs934081843; called by muse, mutect2
- SLC23A1 | c.105C>T p.I35= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs551876429, COSV62297944; called by muse, mutect2, varscan2
- SLC27A2 | c.813A>G p.A271= | Silent (SNP) | VAF 21/199 reads (11%) | catalogued as rs555967917; called by muse, mutect2, varscan2
- SLC4A1AP | c.1569A>G p.S523= | Silent (SNP) | VAF 15/153 reads (10%) | catalogued as rs775334227; called by muse, mutect2, varscan2
- SLC7A5 | c.1185C>T p.S395= | Silent (SNP) | VAF 52/689 reads (8%) | catalogued as rs143124103; called by muse, mutect2
139 further variants in this file (0 protein-altering or splice-affecting, 28 silent, 111 other) are not listed here.
